EXCEPTIONAL_RESPONDERS case ER-B0BH — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6bfa0223-d7db-4e9a-9d0e-a131f9d7ad71

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Alive.

Diagnoses (2)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.1 years (23,031 days); AJCC pathologic stage: Stage II.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: recurrence; Age at diagnosis: 68.6 years (25,065 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical stage: Stage IIIA; Prior malignancy: yes; Days to last follow up: 1,667 days (4.6 years); Days to best overall response: 1,122 days (3.1 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 1,073 days (2.9 years); Days to treatment end: 1,739 days (4.8 years).

Follow-up (1 entry)
- Days to follow up: 1,667 days (4.6 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 721 days (2.0 years); Days progression-free: 1,667 days (4.6 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0BH-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Preservation method: FFPE.
  Slide ER-B0BH-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 10; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
